FM case AD9821 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/327f650e-8391-4e52-affe-47a4ea045c95

Male, 70.2 years: diagnosis not reported by GDC of the nervous system; metastasis biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
